TCGA case TCGA-DX-A8BV — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/07a6bbce-012b-48fe-8c62-e79a1b200eb6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Dead; Days to death: 1,845 days (5.1 years).

Diagnoses (3)
1. Fibromyxosarcoma (the primary disease): ICD-O-3 morphology code: 8811/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 57.5 years (21,005 days); Year of diagnosis: 2004; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Liver; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 5.5; Tumor length measurement: 14.5; Tumor width measurement: 13.5.
2. Recurrence of diagnosis 1 (Fibromyxosarcoma), site: Retroperitoneum. Age at diagnosis: 58.5 years (21,362 days); Days to diagnosis: 357 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Liver. Age at diagnosis: 59.1 years (21,578 days); Days to diagnosis: 573 days (1.6 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 357 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 357 days.
- Day 573 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 573 days (1.6 years).
- Days to follow up: 1,845 days (5.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A8BV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 880 mg.
  Slide TCGA-DX-A8BV-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A8BV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A8BV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Myxofibrosarcoma; Margin status: Negative; Tumor total necrosis: Extensive Necrosis (>50%); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 750; Days from index date to pharmaceutical treatment ended: 903; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 750; Days from index date to pharmaceutical treatment ended: 903; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 415; Days from index date to pharmaceutical treatment ended: 446; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Stable Disease.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 415; Days from index date to pharmaceutical treatment ended: 446; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Stable Disease.
- Radiation treatment: Days from index date to radiation therapy started: 496; Days from index date to radiation therapy ended: 537; Radiation therapy type: External; Radiation total dose: 5400; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 30; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Partial Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,845 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,845 days; disease-free interval: event (new tumor event after initially disease-free), 357 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 357 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A8BV-01A-11D-A37B-01): tumor purity 0.51, ploidy 3.45, whole-genome doublings 1.
